Surgical pathology report (de-identified scan), TCGA case TCGA-24-1552, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site Washington University, specimen TCGA-24-1552-01A (Primary Tumor).

[page 1 of 4]
SURGICAL PATHOLOGY REPORT

FINAL

*** Converted Case * This report may not match the original report format**

Patient Name: .

Address:

Gender: F

DOB:

Service:

Location:

MRN :

Hospital #:

Patient Type:

Accession #:

Taken:

Received:

Accessioned:

Reported:

Physician(s):

DIAGNOSIS:

OVARY, LEFT, BILATERAL SALPINGO-OOPHORECTOMY

- SEROUS PAPILLARY ADENOCARCINOMA, POORLY DIFFERENTIATED (T IIIC, FIGO IIIC)
- SEE SYNOPTIC REPORT
- LYMPHOVASCULAR SPACE INVOLVEMENT IDENTIFIED

OMENTUM, OMENTECTOMY - METASTATIC SEROUS ADENOCARCINOMA
- MAXIMUM TUMOR IMPLANT DIMENSION 17 CM

UTERUS, SEROSA, ABDOMINAL HYSTERECTOMY
- METASTATIC SEROUS ADENOCARCINOMA

SOFT TISSUE PERITONEAL IMPLANT, BIOPSY
- METASTATIC SEROUS ADENOCARCINOMA

SOFT TISSUE, CUL-DE-SAC, (FS), BIOPSY
- ADENOCARCINOMA

FALLOPIAN TUBE, RIGHT, BILATERAL SALPINGO-OOPHORECTOMY
- METASTATIC SEROUS ADENOCARCINOMA

UTERUS, CERVIX, ABDOMINAL HYSTERECTOMY
- SQUAMOUS METAPLASIA
- CHRONIC INFLAMMATION
- NO TUMOR IDENTIFIED

UTERUS, ENDOMETRIUM, ABDOMINAL HYSTERECTOMY
- ATROPHY
- NO TUMOR IDENTIFIED

UTERUS, MYOMETRIUM, ABDOMINAL HYSTERECTOMY
- LEIOMYOMATA
- NO TUMOR IDENTIFIED

OVARY, RIGHT, BILATERAL SALPINGO-OOPHORECTOMY
- NO HISTOPATHOLOGIC ABNORMALITY
- NO TUMOR IDENTIFIED

FALLOPIAN TUBE, LEFT, BILATERAL SALPINGO-OOPHORECTOMY
- NO HISTOPATHOLOGIC ABNORMALITY
- NO TUMOR IDENTIFIED

APPENDIX, APPENDECTOMY - NO HISTOPATHOLOGIC ABNORMALITY
- NO TUMOR IDENTIFIED
SOFT TISSUE, CUL-de-SAC, (FS), BIOPSY - ADENOCARCINOMA

[page 2 of 4]
By this signature, I attest that the above diagnosis is based upon my personal examination of the slides (and/or other material indicated in the diagnosis).

***Report Electronically Reviewed and Signed Out By

Intraoperative Consultation:

FS - Soft tissue, cul-de-sac - "Adenocarcinoma,"

Microscopic Description and Comment:

A poorly differentiated papillary serous adenocarcinoma is seen arising from the left ovary. The tumor subtotally replaces the left ovary with prominent lymphovascular space involvement. Metastatic serous adenocarcinoma is seen in the omentum with the largest implant measuring 17 cm in greatest dimension. Tumor implants are identified on the uterine serosa, pelvic soft tissue and peritoneum as well. Tumor is identified on the serosal surface of the right fallopian tube. The right ovary, endometrium, cervix, and left fallopian tube are free of tumor. The nodule noted grossly on the right ovary proved to represent corpora albicans histologically. The right fallopian tube demonstrates scarring with dystrophic calcification as evidence of chronic inflammation. Exuberant squamous metaplasia is seen in the cervix. Benign leiomyomas are identified within the myometrium. The endometrium is atrophic. The additionally submitted appendix is unremarkable and free of tumor.

SYNOPTIC REPORTING FORM FOR MALIGNANT OVARIAN NEOPLASMS

1. A neoplasm is PRESENT.
2. The HISTOLOGIC DIAGNOSIS is: Serous Adenocarcinoma
3. The LOCATION(S) OF THE PRIMARY TUMOR(S) is/are:
Left ovary only
4. The FIGO GRADE of the tumor is:
III (Tumor composed of greater than 50% solid cellular nests)
5. The NUCLEAR (BRODERS') GRADE of the tumor is:
G3 (Poorly-differentiated)
6. Tumor IS identified on the ovarian surface.
7. Tumor DOES NOT invade the mesovarium.
8. Tumor DOES NOT invade the adjacent fallopian tube.
9. Tumor DOES invade the pelvic soft tissue.
10. Tumor involvement of the pelvic peritoneum is PRESENT.
11. Metastatic involvement of the peritoneal is
PRESENT (Specimen submitted as "peritoneal implsnt")
12. Metastatic involvement of the omentum is PRESENT.
13. The maximum dimension of tumor implants outside the true pelvis is 17 cm.
14. Metastatic involvement of the uterine serosa is PRESENT.
15. Metastatic involvement of the endometrium is ABSENT.
16. Regional lymph node metastases CANNOT BE EVALUATED.
17. The total number of regional lymph nodes examined is 0.
18. The total number of metastatically-involved regional lymph nodes is Not evaluable
19. DETAILED STAGING INFORMATION:
Based on the above information, the PRIMARY TUMOR is classified as:

TNM SCHEME	FIGO SCHEME	DEFINITION
T3c	IIIC	Macroscopic peritoneal metastasis beyond true pelvis measuring greater than 2 cm in greatest dimension.

[page 3 of 4]
HISTOLOGICAL PATHOLOGY REPORT

THE REGIONAL LYMPH NODES are classified as:

NX (Nodal status cannot be assessed)

THE STATUS OF DISTANT TUMOR SITES is classified as:

MX (Status cannot be assessed)

20. The FINAL AJCC/FIGO STAGE IS:

AJCC SCHEME

FIGO SCHEME

X

Insufficient data to assign stage

The pathologic stage assigned here should be regarded as provisional, and may change after integration of clinical data not provided with this specimen.

History:

The patient is a year old woman with a pelvic mass. Operative procedure: Total abdominal hysterectomy with bilateral salpingo-oophorectomy, appendectomy and omentectomy.

An intraoperative non-microscopic consultation was obtained and interpreted as: Called to open a uterus with attached ovaries and tubes. The serosal surface and parametrial soft tissue show involvement with tumor implants. The uterus is bivalved in the OR to show a scant endometrial surface. A flat surface lesion consistent with being polyps is present, by

Specimen(s) Received:

A: FS- SOFT TISSUE, CUL DE SAC

B: UTERUS, CERVIX,

C: OMENTUM

D: TUMOR

E: APPENDIX

F: PERITONEAL IMPLANT

Gross Description:

The specimens are received in six containers of formalin, labeled with the patient's name. The first container is labeled "cul-de-sac biopsy, FS1." It contains a 1.1 x 0.3 cm, tan-white to yellow tissue fragment. Labeled FS1. Jar 0.

The second container is additionally labeled "uterus, cervix and BSO." It contains an 8 cm superior to inferior, 5.2 cm cornu-to-cornu and 4.5 cm anterior to posterior 137 gm uterus with attached right and left ovaries and fallopian tubes. There is a 2.7 cm subserosal myoma with an adherent 7.5 x 4 cm fragment of omentum replaced by tumor. The serosa contains other small 0.2 to 0.4 cm tumor implants and a second fragment of attached 2.5 x 2.2 cm omentum replaced by tumor adherent to the serosal surface. The cervix is tan, smooth and unremarkable. The endocervical canal is roughened, tan, and lush. The endometrial cavity measures 3.2 x 2.5 and the endometrium measures up to 0.2 cm with the aforementioned flat polyp measuring 2 cm present in the anterior endometrial cavity. The myometrium measures up to 3.2 cm with multiple tan-white, whorled, well-demarcated nodules measuring up to 1.5 cm. The right ovary measures 1.2 cm in diameter and contains a 0.2 cm firm, white, serosal nodule. The right fallopian tube measures 4.2 x 0.5 cm and is unremarkable. Cut section of the ovary is solid, tan-yellow-white. The left ovary measures 2.8 x 1.6 x 0.9 cm. Cut section is solid, tan-white with focal areas of papillations and surface tumor implants. The left fallopian tube measures 4.2 x 0.5 cm and is unremarkable. Labeled: C1, C2 - anterior cervix and endocervix; C3, C4 - posterior cervix, endocervix; E1 - lower uterine segment; E2 and E3 - anterior endometrium/myometrium; E4, E5 - posterior endometrium/myometrium (E5 contains serosal tumor implant); M - myoma; RO - right ovary; RT - right fallopian tube; LO1 through LO3 - left ovary; LT - left fallopian tube.

The third container is labeled "omentum." It contains two tumor implants measuring 17 x 10 x 4 and 11 x 6 x 3 cm. Labeled: A1 through A3. Jar 5.

The fourth container is labeled "tumor." It contains a 10 x 5 x 3

[page 4 of 4]
SURGICAL PATHOLOGY REPORT

cm aggregate of omentum replaced by tumor implants. Labeled B.

The fifth container is labeled "appendix." It contains an 8.5 x 0.7 cm vermiform appendix with attached fat. The serosa is tan and smooth without tumor implants. Cut section is unremarkable. No tumor identified. The lumen contains what appears to be barium. Labeled D1 and D2. Jar 1.

The sixth container is labeled "peritoneal implant." It contains a 6.5 x 4.8 x 0.5 cm fatty serosal specimen, subtotally replaced by tumor. Labeled G.

Surgical Pathology report is available on-line on _____ and _____

The performance characteristics of some immunohistochemical stains, fluorescence in-situ hybridization tests and immunophenotyping by flow cytometry cited in this report (if any) were determined by the Surgical Pathology Department as part of an ongoing quality assurance program and in compliance with federally mandated regulations drawn from the Clinical Laboratory Improvement Act of 1988 (CLIA '88). Some of these tests rely on the use of "analyzer specific reagents" and are subject to specific labeling requirements by the US Food and Drug Administration. Such diagnostic tests may only be performed in a facility that is certified by the Department of Health and Human Services as a high complexity laboratory under CLIA '88. The FDA has determined that such clearance or approval is not necessary. This test is used for clinical purposes. It should not be regarded as investigational or for research. Nevertheless, federal rules concerning the medical use of analyzer specific reagents require that the following disclaimer be attached to the report.

This test was developed and its performance characteristics determined by the

This has not been cleared or approved by the U. S. Food and Drug Administration.

Source: NCI Genomic Data Commons file 36164f7c-ea7b-4c56-a9e3-8e5c047d19e5 (TCGA-24-1552.FF7B6D0B-D13B-473E-A924-C63CB0B46511.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).